Somatic mutation profile of tumor specimen PCProject_0142_T2_WES (aliquot PCProject_0142_T2_WES_1) from CMI case PCProject_0142, project CMI-MPC: Count Me In (CMI): The Metastatic Prostate Cancer (MPC) Project. Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 57.1 years (20,857 days).
Specimen PCProject_0142_T2_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Prostate; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e51009b1-ce39-4e55-8384-f2d0b6582447.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen PCProject_0142_SALIVA (DNA), aliquot PCProject_0142_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/db408ee5-c84e-4ecc-bce4-dbaa37dd74d5

The open-access MAF lists 24 somatic variants for this specimen: 16 protein-altering or splice-affecting, 6 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 6, Nonsense Mutation 2, Splice Site 2, Frame Shift Del 1, Intron 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CCDC158 | c.1094G>A p.R365H | Missense Mutation (SNP) | VAF 55/232 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs759340288, COSV66355718; called by muse, mutect2, varscan2
- FLT4 | c.875C>A p.S292Y | Missense Mutation (SNP) | VAF 158/576 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV56098383; called by muse, mutect2, varscan2
- PCDHA12 | c.2045C>T p.A682V | Missense Mutation (SNP) | VAF 231/848 reads (27%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.001); catalogued as rs782271327; called by muse, mutect2, varscan2
- PCDHB14 | c.2185G>A p.E729K | Missense Mutation (SNP) | VAF 163/579 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.028); catalogued as rs782635187, COSV53387623, COSV99505966; called by muse, mutect2, varscan2
- RBMXL2 | c.797G>A p.R266H | Missense Mutation (SNP) | VAF 79/368 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs192864844; called by muse, mutect2, varscan2
- SLC7A14 | c.342G>T p.K114N | Missense Mutation (SNP) | VAF 66/220 reads (30%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); catalogued as COSV99200454; called by muse, varscan2
- SMC3 | c.1825A>G p.M609V | Missense Mutation (SNP) | VAF 35/140 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); catalogued as COSV62422785; called by muse, mutect2, varscan2
- TAF1L | c.760C>T p.R254* | Nonsense Mutation (SNP) | VAF 17/96 reads (18%) | catalogued as rs761429692, COSV54258619; called by muse, mutect2, varscan2
- YARS1 | c.1123A>G p.I375V | Missense Mutation (SNP) | VAF 52/270 reads (19%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as rs761381786; called by muse, mutect2, varscan2
- ATP2A2 | c.220-1G>A p.X74_splice | Splice Site (SNP) | VAF 61/359 reads (17%) | called by muse, mutect2, varscan2
- BICDL1 | c.662G>A p.R221K | Missense Mutation (SNP) | VAF 30/184 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- CNR1 | c.346C>A p.Q116K | Missense Mutation (SNP) | VAF 10/179 reads (6%) | SIFT tolerated (0.81); PolyPhen benign (0.04); called by muse, mutect2
- FBXL6 | c.513del p.K172Rfs*28 | Frame Shift Del (DEL) | VAF 63/234 reads (27%) | called by mutect2, pindel, varscan2
- KAT7 | c.953C>T p.S318L | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.724); called by muse, mutect2, varscan2
- SPTA1 | c.2899-1G>A p.X967_splice | Splice Site (SNP) | VAF 43/205 reads (21%) | called by muse, mutect2, varscan2
- TDRD10 | c.706C>T p.Q236* | Nonsense Mutation (SNP) | VAF 21/360 reads (6%) | called by muse, mutect2
- CAPNS1 | c.141C>T p.G47= | Silent (SNP) | VAF 9/69 reads (13%) | catalogued as rs17879825; called by muse, mutect2, varscan2
- DUS4L-BCAP29 | c.228C>G p.T76= | Silent (SNP) | VAF 15/59 reads (25%) | catalogued as rs1450506642; called by muse, mutect2, varscan2
- FKBP9 | c.978C>T p.C326= | Silent (SNP) | VAF 41/173 reads (24%) | called by muse, mutect2, varscan2
- FTMT | c.199C>A p.R67= | Silent (SNP) | VAF 25/109 reads (23%) | catalogued as COSV58419985; called by muse, mutect2, varscan2
- PCDHA9 | c.1461C>T p.N487= | Silent (SNP) | VAF 110/1730 reads (6%) | catalogued as COSV65323655; called by muse, mutect2
- TNFRSF8 | c.396G>A p.P132= | Silent (SNP) | VAF 83/332 reads (25%) | catalogued as rs778414727, COSV55799181; called by muse, mutect2, varscan2
- JAG1 | c.2344+27C>T | Intron (SNP) | VAF 12/286 reads (4%) | called by muse, mutect2
- TUBA8 | c.*2T>C | 3'UTR (SNP) | VAF 46/202 reads (23%) | called by muse, mutect2, varscan2
